Gene-level copy-number profile of tumor specimen TCGA-44-A4SS-01A from TCGA case TCGA-44-A4SS, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 73.9 years (26,991 days).
Specimen TCGA-44-A4SS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.6eee5aea-3573-4e9f-ba7d-63181b36cc7a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-44-A4SS-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/081a1bfb-b82c-469b-bc95-a6eb9715a58b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 76; copy number 1: 20,267; copy number 2: 33,590; copy number 3: 5,668; copy number 4: 120; copy number 6: 34; copy number 15: 49; copy number 24: 14.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-44-A4SS-01A-11D-A24O-01): tumor purity 0.25, ploidy 3.29, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 76 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:21,962,819–22,507,723, 76 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 63 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:38,530,031–39,747,291, 63 genes, copy number 15–24 (within-gene range 4–24) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 17,905. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
